Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7693, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7693-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

Sections demonstrate a diffusely infiltrating glial neoplasm. The tumor is moderately hypercellular. It is composed primarily of cells with round nuclei, prominent perinuclear haloes, and moderate atypia. The tumor cells are admixed with a capillary network with areas of vascular hyalinization, but no true microvascular proliferation, hemorrhage and necrosis. Mitotic figures are rare. Abundant hemosiderin laden macrophages are seen.

Addendum Discussion:

The neoplastic cells demonstrate variable proliferation activity with a calculated MIB-1 labeling index ranging from 3.5-5%. This is an intermediate level of proliferation activity and is most suggestive of a low grade (grade II) tumor.

Diagnosis:

Low grade oligodendroglioma (WHO grade II)

Source: NCI Genomic Data Commons file 7e93ec18-95c6-4ed8-9def-a5b9eda75cdd (TCGA-HT-7693.7AD7AAC7-DF39-4F13-9038-A6685012E8B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).